Gene-level copy-number profile of tumor specimen TCGA-CQ-6225-01A from TCGA case TCGA-CQ-6225, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.7 years (23,988 days).
Specimen TCGA-CQ-6225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c8327f7a-6624-4df6-83e6-7f5d7dffdfb1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-6225-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae17ffec-9c19-488a-9577-25d1f304b647

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 275; copy number 2: 19,307; copy number 3: 12,134; copy number 4: 24,087; copy number 5: 1,586; copy number 6: 1,813; copy number 7: 75; copy number 8: 45; copy number 10: 250; copy number 11: 124; copy number 12: 48; copy number 18: 1; copy number 34: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-6225-01A-11D-1910-01): tumor purity 0.81, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,426,249–188,389,666, 54 genes: C4orf47, CCDC110, AC106897.1, PDLIM3, SORBS2, AC093797.1, AC108472.1, Y_RNA, AC104805.1, AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1.
- chr5:80,654,652–80,876,815, 2 genes (within-gene range 0–2): MSH3, AC022493.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 437 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:188,291,669–188,595,931, 1 gene, copy number 18 (within-gene range 4–18): GULP1.
- chr2:190,534,855–205,620,162, 251 genes, copy number 10–12 (within-gene range 2–12) (broad region; genes not listed).
- chr4:41,842,154–42,657,105, 16 genes, copy number 10 (within-gene range 8–10): HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1.
- chr8:37,934,281–38,560,939, 31 genes, copy number 12: GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr17:39,461,486–41,522,529, 138 genes, copy number 11–34 (within-gene range 4–34) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
